Somatic mutation profile of tumor specimen TCGA-MP-A4TC-01A (aliquot TCGA-MP-A4TC-01A-11D-A24P-08) from TCGA case TCGA-MP-A4TC, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Middle lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 77.9 years (28,471 days).
Specimen TCGA-MP-A4TC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ade490e6-b430-4ee5-8160-52810d506048.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-MP-A4TC-10A (Blood Derived Normal), aliquot TCGA-MP-A4TC-10A-01D-A24P-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/806c719d-7919-46a1-80bf-5239b2d951f3

The open-access MAF lists 281 somatic variants for this specimen: 210 protein-altering or splice-affecting, 66 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 176, Silent 66, Nonsense Mutation 19, Frame Shift Del 6, Splice Site 4, Intron 2, Splice Region 2, In Frame Del 2, RNA 2, Frame Shift Ins 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FH | c.952C>T p.H318Y | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs398123168, CM031677, COSV100844978; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.476C>T p.A159V | Missense Mutation (SNP) | VAF 18/61 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as rs1555526131, COSV52674926, COSV52693942, COSV52759722; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AADACL3 | c.891G>T p.R297S | Missense Mutation (SNP) | VAF 38/139 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.098); catalogued as COSV100206557; called by muse, mutect2, varscan2
- ABCB6 | c.1453G>A p.G485S | Missense Mutation (SNP) | VAF 21/154 reads (14%) | SIFT tolerated (0.74); PolyPhen benign (0.003); catalogued as COSV99202363; called by muse, mutect2, varscan2
- AC098582.1 | c.877G>C p.G293R | Missense Mutation (SNP) | VAF 30/137 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as COSV99985312; called by muse, mutect2, varscan2
- ACTRT2 | c.205C>A p.L69M | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1163318195, COSV101007503; called by muse, mutect2, varscan2
- ADAMTS12 | c.3013C>A p.P1005T | Missense Mutation (SNP) | VAF 139/339 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.058); catalogued as COSV100710316; called by muse, mutect2, varscan2
- ADAMTS9 | c.2119G>A p.D707N | Missense Mutation (SNP) | VAF 36/153 reads (24%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as COSV99898775; called by muse, mutect2, varscan2
- ALPK1 | c.2013G>C p.L671F | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT tolerated (0.5); PolyPhen benign (0.015); catalogued as COSV99453117; called by muse, mutect2, varscan2
- AMPH | c.593G>T p.R198L | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100340988, COSV57738136; called by muse, mutect2, varscan2
- ANKRD33 | c.525G>T p.Q175H (on ENST00000340970 / NM_001304459.2; = p.Q300H on NM_182608.4) | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); catalogued as COSV100001128; called by muse, mutect2
- APOB | c.1213C>A p.P405T | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs61745113, COSV99263768, COSV99266413; called by muse, mutect2, varscan2
- ARFGEF3 | c.784C>T p.P262S | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99292421; called by muse, mutect2, varscan2
- ARID1A | c.2833G>T p.G945* | Nonsense Mutation (SNP) | VAF 12/95 reads (13%) | catalogued as COSV61375911, COSV61380948; called by muse, mutect2, varscan2
- ARL6 | c.349G>A p.D117N | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.061); catalogued as COSV100256387; called by muse, mutect2, varscan2
- ARSG | c.421G>T p.G141* | Nonsense Mutation (SNP) | VAF 28/77 reads (36%) | catalogued as COSV101477871; called by muse, mutect2, varscan2
- ASPM | c.2893G>T p.V965F | Missense Mutation (SNP) | VAF 17/112 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs778251863, COSV99659602, COSV99660959; called by muse, mutect2, varscan2
- AVEN | c.467G>T p.R156L | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as COSV100145281, COSV60733085; called by muse, mutect2, varscan2
- BAIAP2L2 | c.181C>A p.R61S | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.069); catalogued as COSV100140227; called by muse, mutect2, varscan2
- BAMBI | c.369A>T p.Q123H | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.101); catalogued as COSV100977479; called by muse, mutect2, varscan2
- BAZ1B | c.217G>T p.A73S | Missense Mutation (SNP) | VAF 41/199 reads (21%) | SIFT tolerated (0.62); PolyPhen benign (0.334); catalogued as COSV100289603; called by muse, mutect2, varscan2
- BBS12 | c.2021G>T p.R674L | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100044810; called by muse, mutect2, varscan2
- BNIP5 | c.790G>C p.E264Q | Missense Mutation (SNP) | VAF 28/104 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.412); catalogued as COSV101465113; called by muse, varscan2
- BPGM | c.298A>T p.R100W | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100790163; called by muse, mutect2, varscan2
- BRINP3 | c.167G>T p.R56L | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.15); catalogued as COSV66515742, COSV66535700; called by muse, mutect2, varscan2
- BRWD1 | c.1964T>C p.L655P | Missense Mutation (SNP) | VAF 43/115 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs999376981, COSV100312880; called by muse, mutect2, varscan2
- C2orf16 | c.1502T>A p.V501E | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.7); catalogued as COSV100820667, COSV62673820; called by muse, mutect2, varscan2
- C7orf33 | c.104G>T p.R35L | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.058); catalogued as COSV100188703; called by muse, mutect2, varscan2
- CAMK4 | c.448G>T p.E150* | Nonsense Mutation (SNP) | VAF 16/47 reads (34%) | catalogued as COSV99998367; called by muse, mutect2, varscan2
- CASP5 | c.136C>A p.Q46K | Missense Mutation (SNP) | VAF 47/103 reads (46%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.009); catalogued as COSV99507177; called by muse, mutect2, varscan2
- CASR | c.2275G>T p.V759L (on ENST00000490131; = p.V836L on NM_000388.4) | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as CM055917, COSV56142372, COSV99948488; called by muse, mutect2, varscan2
- CDH10 | c.1532G>T p.S511I | Missense Mutation (SNP) | VAF 93/255 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV100050165; called by muse, mutect2, varscan2
- CDK20 | c.584G>T p.G195V (on ENST00000325303 / NM_001039803.3; = p.G174V on NM_012119.4) | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100307975; called by muse, mutect2, varscan2
- CFAP54 | c.6082G>T p.G2028C | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.074); catalogued as COSV100732972; called by muse, mutect2, varscan2
- CHD5 | c.5518C>A p.Q1840K | Missense Mutation (SNP) | VAF 34/120 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.155); catalogued as COSV52414520; called by muse, mutect2, varscan2
- CHIT1 | c.1189C>T p.L397F | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT tolerated (0.4); PolyPhen benign (0.027); catalogued as COSV99705054; called by muse, mutect2, varscan2
- CHML | c.892A>T p.M298L | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.505); catalogued as COSV100087054; called by muse, mutect2, varscan2
- CHRDL1 | c.509G>T p.R170L (on ENST00000372045; = p.R176L on NM_145234.4) | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV54323469, COSV99487727; called by muse, mutect2, varscan2
- CLCN4 | c.1417A>G p.M473V | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.176); catalogued as COSV101073665; called by muse, mutect2, varscan2
- CLDND1 | c.638G>C p.G213A | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.712); catalogued as COSV100360664; called by muse, mutect2, varscan2
- CMPK2 | c.789G>T p.T263= | Splice Region (SNP) | VAF 8/74 reads (11%) | catalogued as rs771969281, COSV56774213; called by muse, mutect2, varscan2
- CNTLN | c.2561G>T p.S854I | Missense Mutation (SNP) | VAF 25/118 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99262906; called by muse, mutect2, varscan2
- CNTN5 | c.1089T>A p.D363E | Missense Mutation (SNP) | VAF 47/115 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99673202, COSV99674036; called by muse, mutect2, varscan2
- COL11A1 | c.4414G>T p.D1472Y | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100615264; called by muse, mutect2, varscan2
- COL19A1 | c.1441G>T p.E481* | Nonsense Mutation (SNP) | VAF 26/90 reads (29%) | catalogued as COSV100505256; called by muse, mutect2, varscan2
- COL26A1 | c.1285C>T p.P429S (on ENST00000313669 / NM_001278563.3; = p.P427S on NM_133457.4) | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.005); catalogued as COSV100561494; called by muse, mutect2, varscan2
- COL6A3 | c.8538G>T p.K2846N | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.957); catalogued as COSV99796290; called by muse, mutect2, varscan2
- CSMD3 | c.3773C>A p.P1258Q (on ENST00000297405 / NM_001363185.1; = p.P1154Q on NM_052900.3) | Missense Mutation (SNP) | VAF 55/135 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52269522; called by muse, mutect2, varscan2
- CSMD3 | c.1118C>A p.T373K | Missense Mutation (SNP) | VAF 57/118 reads (48%) | SIFT tolerated (0.4); PolyPhen benign (0.111); catalogued as COSV99825583, COSV99853178; called by muse, mutect2, varscan2
- CTCFL | c.1673G>T p.W558L | Missense Mutation (SNP) | VAF 38/151 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as COSV99712154, COSV99712186; called by muse, mutect2, varscan2
- CTNND2 | c.2188C>A p.R730S | Missense Mutation (SNP) | VAF 76/145 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100472226, COSV58888689; called by muse, mutect2, varscan2
- CXorf66 | c.349G>A p.D117N | Missense Mutation (SNP) | VAF 45/118 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV100983826, COSV100983949; called by muse, mutect2, varscan2
- DCAF8L1 | c.194C>G p.T65R | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.764); catalogued as COSV101491392; called by muse, mutect2, varscan2
- DENND2C | c.1751G>T p.G584V (on ENST00000393274 / NM_001256404.2; = p.G527V on NM_198459.4) | Missense Mutation (SNP) | VAF 78/304 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101283890, COSV67922734; called by muse, mutect2, varscan2
- DIO2 | c.602G>T p.R201L | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.313); catalogued as rs1404229002, COSV101375821, COSV70444910; called by muse, mutect2, varscan2
- DIRAS2 | c.283G>T p.E95* | Nonsense Mutation (SNP) | VAF 32/151 reads (21%) | catalogued as COSV101005815; called by muse, mutect2, varscan2
- DNAH11 | c.4296G>C p.L1432F | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs771639240, COSV100177352; called by muse, mutect2, varscan2
- DSC2 | c.2350A>T p.I784F | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated (0.88); PolyPhen benign (0.013); catalogued as COSV99199486; called by muse, mutect2, varscan2
- ESPNL | c.1750C>T p.P584S | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.039); catalogued as COSV100547602; called by muse, mutect2, varscan2
- EVC2 | c.787G>T p.A263S | Missense Mutation (SNP) | VAF 14/118 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV60392634, COSV60399802; called by muse, mutect2, varscan2
- FCER1A | c.332-1G>T p.X111_splice | Splice Site (SNP) | VAF 12/71 reads (17%) | catalogued as rs1031397386, COSV100929245, COSV63667271; called by muse, mutect2, varscan2
- FLT3 | c.2570C>A p.P857H | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99607456; called by muse, mutect2, varscan2
- FOXB2 | c.72G>T p.M24I | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100942296; called by muse, mutect2
- FOXL2 | c.128G>T p.G43V | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.027); catalogued as COSV100374344, COSV57726432; called by muse, mutect2, varscan2
- FOXL2NB | c.170C>A p.P57H | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as COSV100374290; called by muse, mutect2, varscan2
- FSHR | c.650C>A p.A217D | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs757886852, COSV100436604; called by muse, mutect2, varscan2
- FUNDC1 | c.346C>T p.R116* | Nonsense Mutation (SNP) | VAF 7/44 reads (16%) | catalogued as COSV65181281, COSV65181912; called by muse, mutect2, varscan2
- GABRG1 | c.938T>C p.M313T | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99777442; called by muse, mutect2, varscan2
- GALNT15 | c.1375G>T p.A459S | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.634); catalogued as rs370292287; called by muse, mutect2, varscan2
- GALNTL6 | c.364C>G p.L122V | Missense Mutation (SNP) | VAF 31/223 reads (14%) | SIFT tolerated (0.57); PolyPhen benign (0.058); catalogued as COSV101487672; called by muse, mutect2, varscan2
- GALNTL6 | c.1222A>T p.R408W | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.418); catalogued as COSV101560118; called by muse, mutect2, varscan2
- GARNL3 | c.1408G>C p.A470P | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.191); catalogued as COSV100149950; called by muse, mutect2, varscan2
- GPRC6A | c.2101C>A p.L701I | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.544); catalogued as COSV100114044; called by muse, mutect2, varscan2
- GPRC6A | c.2100C>A p.C700* | Nonsense Mutation (SNP) | VAF 14/60 reads (23%) | catalogued as rs759427603, COSV100114047; called by muse, mutect2, varscan2
- GRIK2 | c.1969G>A p.A657T | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59744393; called by muse, mutect2, varscan2
- GSTA1 | c.271C>A p.L91M | Missense Mutation (SNP) | VAF 85/331 reads (26%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.717); catalogued as COSV100575453; called by muse, mutect2, varscan2
- HAGH | c.700G>T p.V234L | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.551); catalogued as COSV101272422, COSV68400429; called by muse, mutect2, varscan2
- HK1 | c.1872G>C p.K624N | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.37); PolyPhen benign (0.027); catalogued as COSV100065491; called by muse, mutect2, varscan2
- HS3ST1 | c.364G>T p.A122S | Missense Mutation (SNP) | VAF 23/103 reads (22%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.83); catalogued as COSV50023165, COSV99136666; called by muse, mutect2, varscan2
- KCNA1 | c.25G>C p.V9L | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); catalogued as COSV101230126; called by muse, mutect2, varscan2
- KCNA3 | c.634C>G p.P212A | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100871201; called by muse, mutect2, varscan2
- KCNK2 | c.1099G>T p.A367S (on ENST00000444842 / NM_001017425.3; = p.A352S on NM_014217.4) | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT tolerated (0.85); PolyPhen benign (0.013); catalogued as COSV101221868; called by muse, mutect2, varscan2
- KCNT2 | c.1364C>G p.S455C | Missense Mutation (SNP) | VAF 27/140 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99651676, COSV99652135; called by muse, mutect2, varscan2
- KLF4 | c.865G>T p.G289C | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.391); catalogued as COSV101012646; called by muse, mutect2, varscan2
- LATS1 | c.527A>T p.Q176L | Missense Mutation (SNP) | VAF 35/96 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.321); catalogued as COSV99485348; called by muse, mutect2, varscan2
- LILRA4 | c.567C>A p.N189K | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.298); catalogued as COSV99392911; called by muse, mutect2
- LINS1 | c.489+1G>T p.X163_splice | Splice Site (SNP) | VAF 6/23 reads (26%) | catalogued as COSV100129975; called by muse, mutect2, varscan2
- LLGL2 | c.2434C>G p.L812V | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.36); PolyPhen benign (0.078); catalogued as COSV99388994; called by muse, mutect2, varscan2
- LRP2 | c.3181G>T p.G1061C | Missense Mutation (SNP) | VAF 52/285 reads (18%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.885); catalogued as COSV99786657; called by muse, mutect2, varscan2
- LRRC3B | c.519A>T p.K173N | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV101185689; called by muse, mutect2, varscan2
- LRTM2 | c.239T>G p.L80R | Missense Mutation (SNP) | VAF 25/120 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99765068; called by muse, mutect2, varscan2
- LTN1 | c.1055G>T p.G352V | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV100797880; called by muse, mutect2, varscan2
- LTN1 | c.1054G>T p.G352C | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.988); catalogued as rs868211737, COSV100797881; called by muse, mutect2, varscan2
- MAGEC3 | c.820C>G p.R274G | Missense Mutation (SNP) | VAF 45/136 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100024904; called by muse, mutect2, varscan2
- MAP9 | c.1720A>T p.K574* | Nonsense Mutation (SNP) | VAF 14/53 reads (26%) | catalogued as COSV100250743; called by muse, mutect2, varscan2
- MARCHF11 | c.1039C>A p.P347T | Missense Mutation (SNP) | VAF 21/122 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.053); catalogued as COSV100197421; called by muse, mutect2, varscan2
- MMP17 | c.1205-1G>A p.X402_splice | Splice Site (SNP) | VAF 20/87 reads (23%) | catalogued as rs867479923, COSV100861864; called by muse, mutect2, varscan2
- MROH9 | c.1058G>T p.C353F | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV100882690; called by muse, mutect2, varscan2
- MSTO1 | c.679G>T p.G227C | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99824085; called by muse, mutect2, varscan2
- MUC16 | c.22546G>A p.D7516N | Missense Mutation (SNP) | VAF 25/103 reads (24%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.534); catalogued as COSV101198275; called by muse, mutect2, varscan2
- MUC2 | c.972C>A p.F324L | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT tolerated (0.08); catalogued as COSV100363856; called by muse, mutect2, varscan2
- MXRA5 | c.2010G>T p.K670N | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.521); catalogued as COSV99475885; called by muse, mutect2, varscan2
- MYO16 | c.985C>G p.P329A | Missense Mutation (SNP) | VAF 31/130 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.115); catalogued as COSV51812337, COSV51824014; called by muse, mutect2, varscan2
- MYO7B | c.4928C>T p.A1643V | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.119); catalogued as COSV101267891; called by muse, mutect2, varscan2
- N4BP2L2 | c.2218G>T p.D740Y (on ENST00000674422; = p.D311Y on NM_033111.4) | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV100678764; called by muse, mutect2, varscan2
- NCKAP5 | c.5183C>T p.P1728L | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100490135; called by muse, mutect2, varscan2
- NECTIN4 | c.248A>T p.H83L | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.147); catalogued as COSV100919817; called by muse, mutect2, varscan2
- NOTCH4 | c.1725C>G p.C575W | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100900376, COSV66682030; called by muse, varscan2
- NUP210 | c.4558C>T p.P1520S | Missense Mutation (SNP) | VAF 32/103 reads (31%) | SIFT tolerated (0.69); PolyPhen benign (0.009); catalogued as COSV99595598; called by muse, mutect2, varscan2
- OBSCN | c.17794T>C p.C5932R | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99473154; called by muse, mutect2, varscan2
- OR10AG1 | c.364C>G p.Q122E | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.028); catalogued as COSV100399984, COSV56632538; called by muse, mutect2
- OR1S1 | c.537G>C p.L179F | Missense Mutation (SNP) | VAF 56/176 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100515250, COSV58707213; called by muse, mutect2, varscan2
- OR4C16 | c.676C>A p.H226N | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV100113859; called by muse, mutect2, varscan2
- OR52I2 | c.652del p.A218Hfs*13 | Frame Shift Del (DEL) | VAF 55/233 reads (24%) | catalogued as COSV57045033; called by mutect2, pindel, varscan2
- OR6M1 | c.13A>G p.S5G | Missense Mutation (SNP) | VAF 5/81 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as COSV58433887; called by muse, mutect2
- OSR2 | c.722G>T p.R241I | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV99882293; called by muse, mutect2
- PCDHA11 | c.2155G>A p.A719T | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.424); catalogued as COSV100247809; called by muse, mutect2, varscan2
- PCDHGA2 | c.1900G>T p.D634Y | Missense Mutation (SNP) | VAF 38/142 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as COSV54032423, COSV99531298; called by muse, mutect2, varscan2
- PDE3A | c.1946C>A p.P649H | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.161); catalogued as COSV100761509; called by muse, mutect2, varscan2
- PDE4DIP | c.3685G>C p.D1229H | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100516749; called by mutect2, varscan2
- PDZD2 | c.2569-1G>A p.X857_splice | Splice Site (SNP) | VAF 20/189 reads (11%) | catalogued as COSV99223802; called by muse, mutect2, varscan2
- PDZD2 | c.8293G>C p.D2765H | Missense Mutation (SNP) | VAF 17/129 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99223803; called by muse, mutect2, varscan2
- PDZD4 | c.2238G>A p.M746I | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT deleterious (0); PolyPhen benign (0.023); catalogued as COSV99381065; called by muse, mutect2, varscan2
- PEX14 | c.850G>T p.E284* | Nonsense Mutation (SNP) | VAF 5/26 reads (19%) | catalogued as COSV100749990; called by muse, mutect2, varscan2
- PGAP4 | c.61G>T p.G21C | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.634); catalogued as rs533828386, COSV100877774; called by muse, mutect2
- PHF1 | c.859A>T p.S287C | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.955); catalogued as COSV100992572; called by muse, mutect2, varscan2
- PIK3C2G | c.3610G>T p.E1204* (on ENST00000676171; = p.E1163* on NM_004570.5) | Nonsense Mutation (SNP) | VAF 3/15 reads (20%) | catalogued as COSV56810072; called by muse, mutect2
- PKHD1 | c.6519G>A p.M2173I | Missense Mutation (SNP) | VAF 49/161 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as rs754054676, COSV100581236; called by muse, mutect2, varscan2
- PLEKHH2 | c.4005T>A p.C1335* | Nonsense Mutation (SNP) | VAF 14/90 reads (16%) | catalogued as COSV99174355; called by muse, mutect2, varscan2
- PNMA1 | c.599G>A p.R200Q | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.868); catalogued as COSV99678609; called by muse, mutect2, varscan2
- PODN | c.814C>A p.L272M (on ENST00000395871; = p.L224M on NM_153703.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 38/212 reads (18%) | SIFT tolerated (0.37); PolyPhen benign (0.2); catalogued as COSV100439350; called by muse, mutect2, varscan2
- POTEF | c.2446C>A p.R816S | Missense Mutation (SNP) | VAF 43/275 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.533); catalogued as COSV62540059, COSV62540134; called by muse, mutect2, varscan2
- PPP1R3A | c.163G>T p.D55Y | Missense Mutation (SNP) | VAF 24/145 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.538); catalogued as COSV99492000; called by muse, mutect2, varscan2
- PROM2 | c.2381C>T p.P794L | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.63); catalogued as COSV58300783; called by muse, mutect2, varscan2
- PRRC2C | c.2789G>C p.G930A (on ENST00000367742; = p.G928A on NM_015172.4) | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.664); catalogued as COSV100144704; called by muse, mutect2, varscan2
- PRSS1 | c.290C>G p.P97R | Missense Mutation (SNP) | VAF 31/231 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100297756; called by muse, mutect2, varscan2
- PSG7 | c.256G>T p.G86C | Missense Mutation (SNP) | VAF 211/492 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.851); catalogued as rs781911242, COSV101343203, COSV68444770; called by muse, mutect2, varscan2
- PTPN13 | c.1807G>C p.A603P | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100364070; called by muse, mutect2
- PTPN13 | c.1808C>A p.A603E | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100364074; called by muse, mutect2, varscan2
- PTPRD | c.2827G>T p.V943F | Missense Mutation (SNP) | VAF 15/120 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.021); catalogued as COSV100643465; called by muse, mutect2, varscan2
- PTPRH | c.2965G>T p.V989F | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54742622, COSV99670704; called by muse, mutect2, varscan2
- RALGAPB | c.497T>G p.L166* | Nonsense Mutation (SNP) | VAF 13/146 reads (9%) | catalogued as COSV99484753; called by muse, mutect2
- RELL2 | c.414C>G p.S138R | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV99781172; called by muse, mutect2, varscan2
- RFX4 | c.764G>A p.C255Y (on ENST00000392842 / NM_213594.3; = p.C161Y on NM_032491.6) | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as COSV99985396; called by muse, mutect2, varscan2
- RIMS2 | c.2227C>T p.Q743* (on ENST00000666250 / NM_001348490.2; = p.Q551* on NM_014677.5 and 7 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 24/65 reads (37%) | catalogued as COSV99161824; called by muse, mutect2, varscan2
- RIN1 | c.830A>T p.Q277L | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT tolerated (0.12); PolyPhen benign (0.014); catalogued as COSV100254369; called by muse, mutect2, varscan2
- ROR2 | c.2782G>T p.D928Y | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.956); catalogued as COSV100995534; called by muse, mutect2, varscan2
- SAGE1 | c.2587G>T p.V863F | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.918); catalogued as rs782593179, COSV100186697; called by muse, mutect2, varscan2
- SAMSN1 | c.522C>G p.F174L | Missense Mutation (SNP) | VAF 14/113 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53468360, COSV99580696; called by muse, mutect2, varscan2
- SCN7A | c.2981C>A p.A994D | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.723); catalogued as rs372297374; called by muse, mutect2, varscan2
- SDR42E1 | c.303G>C p.R101S | Missense Mutation (SNP) | VAF 31/118 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as COSV100200647; called by muse, mutect2, varscan2
- SEMA3A | c.1226T>A p.M409K | Missense Mutation (SNP) | VAF 21/121 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54884574, COSV99545393; called by muse, mutect2, varscan2
- SETD5 | c.2134G>T p.A712S | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.73); PolyPhen benign (0.212); catalogued as COSV100200175; called by muse, mutect2
- SETDB2 | c.2053G>T p.A685S | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100422433; called by muse, mutect2, varscan2
- SH2D3C | c.826G>T p.E276* (on ENST00000314830 / NM_170600.3; = p.E119* on NM_005489.4) | Nonsense Mutation (SNP) | VAF 15/61 reads (25%) | catalogued as COSV100136432; called by muse, mutect2, varscan2
- SLC10A7 | c.796G>A p.A266T | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.195); catalogued as rs374938794; called by muse, mutect2, varscan2
- SLC4A10 | c.1093C>G p.P365A (on ENST00000446997 / NM_001354461.2; = p.P335A on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/133 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.835); catalogued as COSV55804322, COSV99762592; called by muse, mutect2, varscan2
- SMAD4 | c.502G>T p.G168* | Nonsense Mutation (SNP) | VAF 37/119 reads (31%) | catalogued as COSV61697794; called by muse, mutect2, varscan2
- SPTA1 | c.1684G>T p.A562S | Missense Mutation (SNP) | VAF 42/203 reads (21%) | SIFT tolerated (0.73); PolyPhen benign (0.042); catalogued as COSV100934321, COSV63758424; called by muse, mutect2, varscan2
- STAG3 | c.3311C>T p.P1104L | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV100116637; called by muse, mutect2, varscan2
- STPG4 | c.230A>G p.N77S | Missense Mutation (SNP) | VAF 28/169 reads (17%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.937); catalogued as COSV99681209; called by muse, mutect2, varscan2
- STRIP2 | c.411T>C p.G137= | Splice Region (SNP) | VAF 30/147 reads (20%) | catalogued as COSV99973488; called by muse, mutect2, varscan2
- SULT1E1 | c.61A>G p.K21E | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT tolerated (0.38); PolyPhen benign (0.345); catalogued as COSV99894749; called by muse, mutect2, varscan2
- SUN3 | c.878G>A p.C293Y | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (0.48); PolyPhen benign (0.321); catalogued as COSV99813846; called by muse, mutect2, varscan2
- TEKT2 | c.1161C>A p.D387E | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.699); catalogued as COSV99255393; called by muse, mutect2, varscan2
- TEX264 | c.115G>T p.G39W | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100392496; called by muse, mutect2, varscan2
- TIE1 | c.2971C>G p.L991V | Missense Mutation (SNP) | VAF 26/119 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV100991993, COSV100992110; called by muse, mutect2, varscan2
- TKTL2 | c.1792C>T p.Q598* | Nonsense Mutation (SNP) | VAF 21/116 reads (18%) | catalogued as COSV54918815, COSV99761128; called by muse, mutect2, varscan2
- TLL1 | c.1696G>T p.G566W | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV50268449; called by muse, mutect2, varscan2
- TLR10 | c.427C>T p.H143Y | Missense Mutation (SNP) | VAF 16/113 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.162); catalogued as rs189663400, COSV100457445; called by muse, mutect2, varscan2
- TNR | c.1111C>A p.Q371K | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.706); catalogued as COSV99686788; called by muse, mutect2, varscan2
- TOGARAM1 | c.2623G>T p.D875Y | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.342); catalogued as COSV100817830; called by muse, mutect2, varscan2
- TRDMT1 | c.736A>G p.S246G | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as rs1371732050, COSV100003786; called by muse, mutect2
- TRIM11 | c.1396G>T p.A466S | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.025); catalogued as COSV52860454; called by muse, mutect2, varscan2
- TRIM8 | c.704A>C p.Q235P | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV100193065, COSV100193081; called by muse, mutect2, varscan2
- TRPM6 | c.4106T>G p.V1369G | Missense Mutation (SNP) | VAF 35/198 reads (18%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as COSV100665434; called by muse, mutect2, varscan2
- TRPS1 | c.3038G>T p.S1013I (on ENST00000220888 / NM_001330599.2; = p.S1026I on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 56/151 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as CD155377, COSV99628590; called by muse, mutect2, varscan2
- TTC14 | c.874G>A p.D292N | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.164); catalogued as COSV99931824; called by muse, mutect2, varscan2
- TTN | c.75097G>T p.A25033S (on ENST00000591111; = p.A17609S on NM_003319.4) | Missense Mutation (SNP) | VAF 17/163 reads (10%) | PolyPhen possibly damaging (0.637); catalogued as COSV100595539; called by muse, mutect2
- TUBA3C | c.1224C>A p.Y408* | Nonsense Mutation (SNP) | VAF 45/178 reads (25%) | catalogued as COSV101313836, COSV68027678; called by muse, mutect2, varscan2
- TYK2 | c.3357G>A p.M1119I | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.366); catalogued as COSV99314283; called by muse, mutect2, varscan2
- UGT1A4 | c.164G>T p.G55V | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100529608, COSV59382846; called by muse, mutect2, varscan2
- UGT3A1 | c.1522G>T p.G508C | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.259); catalogued as COSV57102294; called by muse, mutect2, varscan2
- UNC5B | c.131C>G p.A44G | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT tolerated (0.63); PolyPhen benign (0.304); catalogued as COSV100100255; called by muse, mutect2, varscan2
- USH2A | c.2301G>T p.E767D | Missense Mutation (SNP) | VAF 27/156 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as COSV100229419; called by muse, mutect2, varscan2
- VAV3 | c.1864G>T p.G622W | Missense Mutation (SNP) | VAF 24/121 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100579184, COSV58379498; called by muse, mutect2, varscan2
- WDR3 | c.1026G>T p.E342D | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV100831973; called by muse, mutect2, varscan2
- ZBTB41 | c.1222A>T p.R408* | Nonsense Mutation (SNP) | VAF 8/40 reads (20%) | catalogued as COSV100962841; called by muse, mutect2, varscan2
- ZFHX4 | c.3309C>A p.C1103* | Nonsense Mutation (SNP) | VAF 68/162 reads (42%) | catalogued as COSV51485304, COSV99256798; called by muse, mutect2, varscan2
- ZMAT5 | c.226C>T p.H76Y | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.104); catalogued as COSV100722582; called by muse, mutect2
- ZNF318 | c.5012A>G p.Y1671C | Missense Mutation (SNP) | VAF 38/126 reads (30%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); catalogued as rs754449395, COSV58933716; called by muse, mutect2, varscan2
- ZNF350 | c.517C>T p.H173Y | Missense Mutation (SNP) | VAF 93/230 reads (40%) | SIFT tolerated (0.35); PolyPhen benign (0.02); catalogued as COSV54708660; called by muse, mutect2, varscan2
- ZNF648 | c.680C>G p.A227G | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs1022442823, COSV100374438, COSV100374545; called by muse, mutect2
- ZNF71 | c.695A>T p.H232L | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100045600; called by muse, mutect2, varscan2
- ZNF713 | c.440A>T p.H147L (on ENST00000633730 / NM_001366796.2; = p.H160L on NM_182633.3) | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as COSV101448710; called by muse, mutect2, varscan2
- ZNF783 | c.146C>G p.A49G | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV100954141; called by muse, mutect2, varscan2
- DOCK6 | c.1162G>T p.G388C | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FAM47A | c.1916dup p.H639Qfs*2 | Frame Shift Ins (INS) | VAF 23/61 reads (38%) | called by mutect2, pindel, varscan2
- GJA9 | c.96del p.R33Efs*7 | Frame Shift Del (DEL) | VAF 96/350 reads (27%) | called by mutect2, pindel, varscan2
- HEATR1 | c.295del p.I99Ffs*19 | Frame Shift Del (DEL) | VAF 17/118 reads (14%) | called by mutect2, pindel, varscan2
- IGKV3D-11 | c.311C>A p.A104E | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- JMJD1C | c.6121_6122del p.E2041Tfs*5 | Frame Shift Del (DEL) | VAF 16/85 reads (19%) | called by pindel, varscan2
- MYMK | c.368del p.G123Afs*15 | Frame Shift Del (DEL) | VAF 26/107 reads (24%) | called by mutect2, pindel, varscan2
- OR4C15 | c.577C>T p.L193F (on ENST00000314644; = p.L139F on NM_001001920.2) | Missense Mutation (SNP) | VAF 5/125 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.031); called by muse, mutect2
- R3HCC1L | c.516G>T p.E172D | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.044); called by muse, mutect2
- S1PR1 | c.520del p.L174Wfs*62 | Frame Shift Del (DEL) | VAF 20/143 reads (14%) | called by mutect2, pindel, varscan2
- SLC28A3 | c.1352C>A p.A451D | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.908); called by muse, mutect2
- SLC34A2 | c.882_887del p.N295_K296del | In Frame Del (DEL) | VAF 6/48 reads (13%) | called by mutect2, pindel
- SPATA31A1 | c.415C>A p.H139N | Missense Mutation (SNP) | VAF 33/228 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- ZBED8 | c.891_902del p.I298_I301del | In Frame Del (DEL) | VAF 30/154 reads (19%) | called by mutect2, pindel, varscan2
- AKAP17A | c.1779C>T p.D593= | Silent (SNP) | VAF 8/35 reads (23%) | catalogued as rs751536524, COSV100001894; called by muse, mutect2
- AKNAD1 | c.495C>A p.T165= | Silent (SNP) | VAF 23/115 reads (20%) | catalogued as rs753662116, COSV100645332; called by muse, mutect2, varscan2
- ALLC | c.1122G>A p.R374= | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as COSV99377537; called by muse, mutect2, varscan2
- APOBEC3C | c.228C>T p.C76= | Silent (SNP) | VAF 54/220 reads (25%) | catalogued as rs140381208; called by muse, varscan2
- ASGR2 | c.498C>G p.L166= | Silent (SNP) | VAF 20/65 reads (31%) | catalogued as COSV54689990, COSV99642870; called by muse, mutect2, varscan2
- ATP6V1C2 | c.870G>A p.P290= | Silent (SNP) | VAF 19/122 reads (16%) | catalogued as rs771976464, COSV55364155; called by muse, varscan2
- BPIFC | c.429C>T p.I143= | Silent (SNP) | VAF 10/54 reads (19%) | catalogued as COSV100300758; called by muse, mutect2, varscan2
- BRINP2 | c.1755C>T p.V585= | Silent (SNP) | VAF 7/62 reads (11%) | catalogued as COSV100837844; called by muse, mutect2, varscan2
- CCDC126 | c.399G>A p.T133= | Silent (SNP) | VAF 8/45 reads (18%) | catalogued as rs745731281, COSV100277823; called by muse, mutect2, varscan2
- CDH4 | c.585C>A p.S195= | Silent (SNP) | VAF 22/94 reads (23%) | catalogued as COSV100848438; called by muse, mutect2, varscan2
- CHRNA6 | c.408A>G p.T136= | Silent (SNP) | VAF 51/173 reads (29%) | catalogued as COSV99373054, COSV99373110; called by muse, mutect2, varscan2
- CLEC18B | c.120C>A p.A40= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as COSV100375717; called by muse, mutect2, varscan2
- CSMD3 | c.7029A>T p.P2343= (on ENST00000297405 / NM_001363185.1; = p.P2239= on NM_052900.3) | Silent (SNP) | VAF 30/68 reads (44%) | catalogued as COSV99825580; called by muse, mutect2, varscan2
- DENND4B | c.93T>A p.V31= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as rs759557796, COSV100338833; called by muse, mutect2
- DLG2 | c.123C>A p.L41= | Silent (SNP) | VAF 81/193 reads (42%) | catalogued as COSV101070337; called by muse, mutect2, varscan2
- DLG3 | c.1506G>A p.R502= (on ENST00000374360 / NM_021120.4; = p.R165= on NM_020730.3) | Silent (SNP) | VAF 32/71 reads (45%) | catalogued as COSV99529205, COSV99529320; called by muse, mutect2, varscan2
- DYNC2H1 | c.6360A>T p.T2120= | Silent (SNP) | VAF 7/14 reads (50%) | catalogued as COSV100517612; called by muse, mutect2, varscan2
- EPPK1 | c.6255G>T p.V2085= | Silent (SNP) | VAF 60/146 reads (41%) | catalogued as rs782108580, COSV101599738; called by muse, mutect2, varscan2
- FCGBP | c.10428G>T p.P3476= | Silent (SNP) | VAF 50/104 reads (48%) | called by muse, mutect2, varscan2
- FCRL6 | c.642G>T p.G214= | Silent (SNP) | VAF 15/92 reads (16%) | catalogued as COSV100220041; called by muse, mutect2, varscan2
- FLRT2 | c.369C>A p.T123= | Silent (SNP) | VAF 19/105 reads (18%) | catalogued as COSV100420021; called by muse, mutect2, varscan2
- FMN2 | c.288T>C p.D96= | Silent (SNP) | VAF 5/31 reads (16%) | catalogued as COSV100142995; called by muse, mutect2, varscan2
- GALNTL6 | c.961C>A p.R321= | Silent (SNP) | VAF 30/155 reads (19%) | catalogued as COSV101560117, COSV72490120; called by muse, mutect2, varscan2
- HAPLN4 | c.774C>A p.A258= | Silent (SNP) | VAF 11/53 reads (21%) | catalogued as rs781137725, COSV99363629; called by muse, mutect2, varscan2
- HDC | c.1458G>T p.R486= | Silent (SNP) | VAF 11/60 reads (18%) | catalogued as COSV99983846; called by muse, mutect2, varscan2
- IGF2BP2 | c.1677C>T p.V559= | Silent (SNP) | VAF 21/101 reads (21%) | catalogued as COSV100648859; called by muse, mutect2, varscan2
- IGHV3-38 | c.324G>T p.T108= | Silent (SNP) | VAF 35/136 reads (26%) | called by muse, mutect2, varscan2
- INA | c.942G>A p.E314= | Silent (SNP) | VAF 3/31 reads (10%) | catalogued as COSV100878576; called by muse, mutect2
- ITPRID2 | c.3423A>G p.P1141= | Silent (SNP) | VAF 26/163 reads (16%) | catalogued as rs1470904812, COSV100237907; called by muse, mutect2, varscan2
- KANK4 | c.684C>A p.V228= | Silent (SNP) | VAF 9/57 reads (16%) | catalogued as COSV100587045; called by muse, mutect2, varscan2
- KDM1A | c.1830G>A p.T610= | Silent (SNP) | VAF 49/182 reads (27%) | catalogued as rs768258018, COSV100752357; called by muse, mutect2, varscan2
- KIF5C | c.213C>T p.V71= | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as COSV101469514; called by muse, mutect2, varscan2
- KLKB1 | c.1323G>T p.L441= | Silent (SNP) | VAF 12/112 reads (11%) | catalogued as COSV99249647; called by muse, mutect2, varscan2
- KRTAP10-2 | c.225C>T p.C75= | Silent (SNP) | VAF 36/162 reads (22%) | catalogued as COSV100552017; called by muse, mutect2, varscan2
- LRRC66 | c.1296G>T p.A432= | Silent (SNP) | VAF 20/154 reads (13%) | called by muse, mutect2, varscan2
- MTRR | c.1488C>T p.V496= (on ENST00000264668; = p.V469= on NM_002454.3 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 28/248 reads (11%) | catalogued as COSV99241312; called by muse, mutect2
- MYT1L | c.789C>T p.D263= | Silent (SNP) | VAF 37/181 reads (20%) | catalogued as COSV101218936; called by muse, mutect2, varscan2
- NAV3 | c.7059C>A p.L2353= (on ENST00000397909 / NM_001024383.2; = p.L2331= on NM_014903.6) | Silent (SNP) | VAF 20/57 reads (35%) | catalogued as COSV99887177; called by muse, mutect2, varscan2
- NCAPG2 | c.2319C>T p.N773= | Silent (SNP) | VAF 27/130 reads (21%) | catalogued as rs1405555566, COSV99316542; called by muse, mutect2, varscan2
- NEB | c.10305G>T p.P3435= | Silent (SNP) | VAF 33/219 reads (15%) | catalogued as COSV99415147; called by muse, mutect2, varscan2
- NELL2 | c.129C>T p.T43= | Silent (SNP) | VAF 9/45 reads (20%) | catalogued as COSV100418815; called by muse, mutect2, varscan2
- NUP214 | c.5190A>T p.S1730= | Silent (SNP) | VAF 20/98 reads (20%) | catalogued as COSV100845145; called by muse, mutect2, varscan2
- OR1L4 | c.591G>A p.Q197= | Silent (SNP) | VAF 45/397 reads (11%) | catalogued as COSV99413768; called by muse, mutect2, varscan2
- OR2L8 | c.144C>A p.I48= | Silent (SNP) | VAF 106/518 reads (20%) | catalogued as rs1333082369, COSV100594039, COSV61726490; called by muse, mutect2, varscan2
- PCDH11X | c.2934C>A p.I978= | Silent (SNP) | VAF 44/130 reads (34%) | catalogued as COSV100008483, COSV53467701; called by muse, mutect2, varscan2
- PCDHB9 | c.237A>G p.S79= | Silent (SNP) | VAF 22/76 reads (29%) | called by muse, mutect2, varscan2
- PCDHGB1 | c.2094C>G p.L698= | Silent (SNP) | VAF 52/207 reads (25%) | catalogued as COSV53907040, COSV99531300; called by muse, mutect2, varscan2
- PHEX | c.1962T>C p.F654= | Silent (SNP) | VAF 42/96 reads (44%) | catalogued as rs756752961, COSV101039405; called by muse, mutect2, varscan2
- PKHD1 | c.7593G>T p.L2531= | Silent (SNP) | VAF 12/57 reads (21%) | catalogued as COSV100581231; called by muse, mutect2, varscan2
- PPDPFL | c.60C>T p.S20= | Silent (SNP) | VAF 23/66 reads (35%) | catalogued as COSV100293031; called by muse, mutect2, varscan2
- PRAMEF2 | c.1146C>T p.F382= | Silent (SNP) | VAF 22/255 reads (9%) | catalogued as rs1557629847, COSV99534831; called by muse, mutect2
- PTH2R | c.888G>C p.V296= | Silent (SNP) | VAF 10/102 reads (10%) | catalogued as COSV99782115; called by muse, mutect2
- RETREG1 | c.1275C>T p.I425= (on ENST00000306320 / NM_001034850.2; = p.I284= on NM_019000.4) | Silent (SNP) | VAF 20/139 reads (14%) | catalogued as COSV100103844; called by muse, mutect2, varscan2
- RNF112 | c.414G>T p.L138= | Silent (SNP) | VAF 3/10 reads (30%) | catalogued as COSV101518334; called by muse, mutect2
- ROR2 | c.2781G>A p.G927= | Silent (SNP) | VAF 16/90 reads (18%) | catalogued as COSV100995535; called by muse, mutect2, varscan2
- SCN7A | c.2982C>A p.A994= | Silent (SNP) | VAF 6/66 reads (9%) | catalogued as COSV101313092; called by muse, mutect2, varscan2
- SIRT2 | c.498G>T p.T166= | Silent (SNP) | VAF 36/100 reads (36%) | catalogued as rs139101702, COSV99979212; called by muse, mutect2, varscan2
- SNAPC4 | c.4032G>A p.L1344= | Silent (SNP) | VAF 11/52 reads (21%) | catalogued as rs779101729, COSV100046829; called by muse, mutect2, varscan2
- SNRNP200 | c.5406C>T p.I1802= | Silent (SNP) | VAF 20/93 reads (22%) | catalogued as COSV100107133; called by muse, mutect2, varscan2
- SRSF7 | c.259C>A p.R87= | Silent (SNP) | VAF 11/69 reads (16%) | catalogued as COSV100492530; called by muse, mutect2
- TBC1D22B | c.861A>G p.V287= | Silent (SNP) | VAF 27/120 reads (23%) | catalogued as COSV100996680; called by muse, mutect2, varscan2
- TNXB | c.9042C>T p.T3014= (on ENST00000647633; = p.T2767= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 6/90 reads (7%) | catalogued as rs760906844, COSV64492719; ClinVar: uncertain significance; called by muse, mutect2
- TPR | c.5422C>A p.R1808= | Silent (SNP) | VAF 24/96 reads (25%) | catalogued as COSV100823650, COSV66599810; called by muse, mutect2, varscan2
- TRPM3 | c.1731G>A p.E577= (on ENST00000357533 / NM_001366142.2; = p.E410= on NM_020952.6) | Silent (SNP) | VAF 12/49 reads (24%) | catalogued as COSV100676680; called by muse, mutect2, varscan2
- YBX2 | c.591A>T p.A197= | Silent (SNP) | VAF 56/139 reads (40%) | catalogued as COSV99142650; called by muse, mutect2, varscan2
- ZNF385D | c.54C>T p.A18= | Silent (SNP) | VAF 14/58 reads (24%) | catalogued as COSV99873414; called by muse, mutect2, varscan2
- DCHS2 | n.4152del | RNA (DEL) | VAF 8/51 reads (16%) | catalogued as COSV100601056, COSV61768903; called by mutect2, pindel, varscan2
- MGST3 | c.-104+959G>T | Intron (SNP) | VAF 22/105 reads (21%) | catalogued as COSV100903326; called by muse, mutect2, varscan2
- MIR920 | n.56G>A | RNA (SNP) | VAF 21/116 reads (18%) | catalogued as rs766480187, COSV101290046; called by muse, mutect2, varscan2
- SEC13 | c.4-1175C>A | Intron (SNP) | VAF 6/23 reads (26%) | catalogued as rs1307390435, COSV100491241; called by muse, mutect2, varscan2
- SLITRK2 | c.*2G>A | 3'UTR (SNP) | VAF 15/49 reads (31%) | catalogued as COSV100157345, COSV100158319; called by muse, mutect2, varscan2
